Somatic mutation profile of tumor specimen MP2PRT-PAUXDG-TMP1-A (aliquot MP2PRT-PAUXDG-TMP1-A-1-0-D-A81Q-36) from MP2PRT case MP2PRT-PAUXDG, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.1 years (2,218 days).
Specimen MP2PRT-PAUXDG-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6783b440-1545-4f09-8367-056a35d03a3e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUXDG-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUXDG-NB1-A-1-0-D-A81Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0b559c36-5927-4c11-a2b6-81eca1abe4ba

The open-access MAF lists 51 somatic variants for this specimen: 43 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 7, Frame Shift Del 1, Splice Region 1, Intron 1, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AFF2 | c.302C>T p.S101F | Missense Mutation (SNP) | VAF 30/450 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV60664320; called by muse, mutect2
- CENPF | c.5416G>C p.E1806Q | Missense Mutation (SNP) | VAF 9/181 reads (5%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.511); catalogued as COSV65275441; called by muse, mutect2
- CFAP54 | c.6274C>G p.L2092V | Missense Mutation (SNP) | VAF 8/125 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); catalogued as COSV61575570; called by muse, mutect2
- COL12A1 | c.1504G>A p.D502N | Missense Mutation (SNP) | VAF 10/281 reads (4%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.881); catalogued as COSV59408992; called by muse, mutect2
- DERPC | c.224C>T p.S75L | Missense Mutation (SNP) | VAF 94/346 reads (27%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.07); catalogued as rs758617404; called by muse, mutect2, varscan2
- EXT1 | c.827G>A p.G276E | Missense Mutation (SNP) | VAF 110/350 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1038559683; called by muse, mutect2, varscan2
- FAT1 | c.4892C>T p.A1631V | Missense Mutation (SNP) | VAF 55/253 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as rs751475602, COSV71674405; called by muse, mutect2, varscan2
- IL10RA | c.1507G>C p.E503Q | Missense Mutation (SNP) | VAF 32/424 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.559); catalogued as COSV57140704; called by muse, mutect2
- LRP1B | c.5382C>A p.D1794E | Missense Mutation (SNP) | VAF 10/240 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV67288360; called by muse, mutect2
- MAPK8IP2 | c.1271C>T p.A424V | Missense Mutation (SNP) | VAF 119/422 reads (28%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); catalogued as rs928785607; called by muse, mutect2, varscan2
- NXPE3 | c.1375C>T p.R459W | Missense Mutation (SNP) | VAF 17/361 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs914301439; called by muse, mutect2
- PCDH17 | c.1541C>T p.S514L | Missense Mutation (SNP) | VAF 12/332 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.888); catalogued as rs1364348588, COSV64971600; called by muse, mutect2
- PCDHGB2 | c.1630G>A p.A544T | Missense Mutation (SNP) | VAF 31/704 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.379); catalogued as rs1328174006, COSV99533891; called by muse, mutect2
- PLOD1 | c.61G>A p.D21N | Missense Mutation (SNP) | VAF 31/559 reads (6%) | SIFT tolerated (0.37); PolyPhen benign (0.223); catalogued as rs940462451; called by muse, mutect2
- SAFB2 | c.2209C>T p.R737* | Nonsense Mutation (SNP) | VAF 16/280 reads (6%) | catalogued as COSV53042934; called by muse, mutect2
- SAGE1 | c.1425G>A p.M475I | Missense Mutation (SNP) | VAF 10/314 reads (3%) | SIFT tolerated (0.1); PolyPhen benign (0.384); catalogued as COSV61015986; called by muse, mutect2
- SHPRH | c.4624G>C p.D1542H (on ENST00000275233 / NM_001042683.3; = p.D1546H on NM_173082.3) | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs1037603361; called by muse, mutect2
- SNTG1 | c.490G>A p.G164S | Missense Mutation (SNP) | VAF 22/255 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); catalogued as rs1020112242; called by muse, mutect2
- SVEP1 | c.7604C>T p.A2535V | Missense Mutation (SNP) | VAF 28/473 reads (6%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs1446759352; called by muse, mutect2
- ULK1 | c.3003G>C p.E1001D | Missense Mutation (SNP) | VAF 19/582 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV58859511; called by muse, mutect2
- WT1 | c.800C>T p.S267L | Missense Mutation (SNP) | VAF 100/469 reads (21%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.094); catalogued as COSV60086494; called by muse, mutect2, varscan2
- AATF | c.511G>C p.E171Q | Missense Mutation (SNP) | VAF 58/627 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.368); called by muse, mutect2
- ACAD11 | c.89del p.N30Tfs*15 | Frame Shift Del (DEL) | VAF 109/458 reads (24%) | called by mutect2, pindel, varscan2
- AIG1 | c.497C>G p.S166C | Missense Mutation (SNP) | VAF 20/256 reads (8%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.754); called by muse, mutect2
- BPNT2 | c.962A>G p.E321G | Missense Mutation (SNP) | VAF 89/363 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- BUB1B | c.1898C>G p.S633C | Missense Mutation (SNP) | VAF 28/394 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); called by muse, mutect2
- CHFR | c.1265+1G>A p.X422_splice (on ENST00000432561 / NM_001161345.1; = p.X381_splice on NM_018223.2) | Splice Site (SNP) | VAF 62/190 reads (33%) | called by muse, mutect2, varscan2
- CPA3 | c.1016C>T p.S339L | Missense Mutation (SNP) | VAF 14/336 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.122); called by muse, mutect2
- FIZ1 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 179/654 reads (27%) | SIFT tolerated (0.82); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- GLDN | c.405C>G p.I135M | Missense Mutation (SNP) | VAF 16/429 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2
- GLI2 | c.1338C>G p.I446M (on ENST00000361492 / NM_001374353.1; = p.I463M on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 108/315 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- GOLGA4 | c.874G>C p.E292Q | Missense Mutation (SNP) | VAF 32/318 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- GRM3 | c.1825G>C p.A609P | Missense Mutation (SNP) | VAF 96/308 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGSF22 | c.*475G>A | Splice Region (SNP) | VAF 14/246 reads (6%) | called by muse, mutect2
- LRRIQ3 | c.177C>A p.N59K | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.09); called by mutect2, varscan2
- NMNAT3 | c.184C>G p.H62D (on ENST00000296202 / NM_001320512.1; = p.H25D on NM_178177.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/426 reads (7%) | SIFT tolerated (0.57); PolyPhen benign (0.007); called by muse, mutect2
- OR51S1 | c.892C>T p.L298F | Missense Mutation (SNP) | VAF 21/305 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); called by muse, mutect2
- RAG2 | c.937C>T p.H313Y | Missense Mutation (SNP) | VAF 13/366 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2
- RNF215 | c.1063T>G p.W355G | Missense Mutation (SNP) | VAF 108/300 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SHROOM4 | c.3853G>C p.E1285Q | Missense Mutation (SNP) | VAF 28/414 reads (7%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.877); called by muse, mutect2
- TAOK3 | c.2545G>C p.E849Q | Missense Mutation (SNP) | VAF 16/243 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2
- TRIM3 | c.1081G>C p.E361Q | Missense Mutation (SNP) | VAF 140/556 reads (25%) | SIFT tolerated (0.58); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- XDH | c.1604A>C p.K535T | Missense Mutation (SNP) | VAF 70/198 reads (35%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- CASR | c.2154G>C p.R718= (on ENST00000490131; = p.R795= on NM_000388.4) | Silent (SNP) | VAF 12/332 reads (4%) | called by muse, mutect2
- ESYT3 | c.2223C>T p.I741= | Silent (SNP) | VAF 16/248 reads (6%) | called by muse, mutect2
- MTHFSD | c.33G>A p.Q11= (on ENST00000360900 / NM_001159377.2; = p.Q10= on NM_022764.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/252 reads (4%) | called by muse, mutect2
- NCAPH2 | c.288G>A p.S96= | Silent (SNP) | VAF 83/259 reads (32%) | catalogued as rs374607010, COSV100237849; called by muse, mutect2, varscan2
- NPFFR2 | c.222G>C p.R74= | Silent (SNP) | VAF 15/444 reads (3%) | catalogued as COSV58151359; called by muse, mutect2
- PNPLA1 | c.1251T>A p.S417= (on ENST00000394571 / NM_001374623.1; = p.S322= on NM_173676.2) | Silent (SNP) | VAF 56/459 reads (12%) | called by muse, mutect2, varscan2
- SECTM1 | c.357C>T p.L119= | Silent (SNP) | VAF 34/424 reads (8%) | catalogued as rs1486057103, COSV99486191; called by muse, mutect2
- CABP1 | c.655-4011G>C | Intron (SNP) | VAF 29/300 reads (10%) | catalogued as rs1453246266; called by muse, varscan2
